CCDI case PBBSFF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/d157238d-acdf-4f4a-af48-e1b1c0789b67

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.8 years (6,126 days).

Biospecimens (3 samples)
- Sample 0DFKHG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFKHH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFKHJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
